Somatic mutation profile of tumor specimen MP2PRT-PAPSAW-TMP1-A (aliquot MP2PRT-PAPSAW-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPSAW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.1 years (780 days).
Specimen MP2PRT-PAPSAW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad8329b4-17c7-4a04-9f0b-6cec10409068.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPSAW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPSAW-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/178da7d8-a279-49cb-960f-07c756490394

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 78/189 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- OTOG | c.5221G>A p.G1741R | Missense Mutation (SNP) | VAF 180/377 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.07); catalogued as rs368666159, COSV61130787; called by muse, mutect2, varscan2
- TBC1D3B | c.1060C>A p.Q354K | Missense Mutation (SNP) | VAF 4/418 reads (1%) | SIFT tolerated (0.98); PolyPhen possibly damaging (0.614); catalogued as rs306818; called by muse, mutect2
- VIPR2 | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 66/156 reads (42%) | catalogued as rs200422000; called by muse, varscan2
- DNASE2B | c.599C>A p.A200D | Missense Mutation (SNP) | VAF 96/213 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRB14 | c.720C>G p.F240L | Missense Mutation (SNP) | VAF 5/141 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.131); called by muse, mutect2
- AXIN2 | c.2478G>A p.T826= | Silent (SNP) | VAF 16/272 reads (6%) | catalogued as rs148159432; ClinVar: likely benign; called by muse, mutect2
- DNAH9 | c.11160C>T p.D3720= | Silent (SNP) | VAF 109/216 reads (50%) | catalogued as rs767969724; called by muse, mutect2, varscan2
- CTBP2 | c.58+12742T>C | Intron (SNP) | VAF 159/769 reads (21%) | called by muse, mutect2, varscan2
